Somatic mutation profile of tumor specimen ALCH-B1MZ-TTP1-A (aliquot ALCH-B1MZ-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1MZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.1 years (23,042 days).
Specimen ALCH-B1MZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8d76e05-8897-4053-ba47-8ab4c5c815eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MZ-NB1-A (Blood Derived Normal), aliquot ALCH-B1MZ-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e74b39ab-fc22-483e-aa8d-27408d674e6e

The open-access MAF lists 484 somatic variants for this specimen: 326 protein-altering or splice-affecting, 106 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 106, Intron 24, Nonsense Mutation 20, RNA 12, Frame Shift Del 9, 3'UTR 5, Splice Site 5, 3'Flank 5, 5'UTR 4, Splice Region 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 117/306 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 152/352 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419913; called by muse, mutect2, varscan2
- ADAM33 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766778990; called by muse, mutect2, varscan2
- ADAMTS5 | c.1209C>A p.H403Q | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as COSV53176232, COSV99034717; called by muse, mutect2, varscan2
- AFDN | c.5167G>T p.D1723Y (on ENST00000447894 / NM_001366320.1; = p.D1680Y on NM_001291964.1) | Missense Mutation (SNP) | VAF 136/347 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs372723744; called by muse, varscan2
- ALDH1L2 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1195129438, COSV51560658; called by muse, mutect2, varscan2
- AMPH | c.1608G>A p.Q536= | Splice Region (SNP) | VAF 18/248 reads (7%) | catalogued as COSV57747199; called by muse, mutect2
- ASPM | c.6032G>T p.R2011I | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54137092; called by muse, mutect2
- ATRNL1 | c.2478G>T p.M826I | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV58110871; called by muse, mutect2, varscan2
- ATRX | c.5847C>A p.D1949E | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as COSV64873696; called by muse, mutect2, varscan2
- BRF1 | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 145/268 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV59266373; called by muse, mutect2, varscan2
- C6 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.088); catalogued as rs867324227; called by muse, mutect2, varscan2
- CACNA1F | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 139/688 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs782399050, COSV100544314, COSV59906506; called by muse, mutect2, varscan2
- CATSPERD | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 173/540 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs371791746; called by muse, mutect2
- CDKN2A | c.263del p.E88Gfs*58 | Frame Shift Del (DEL) | VAF 157/529 reads (30%) | catalogued as COSV58728274, COSV58728388, COSV58729766; called by mutect2, pindel, varscan2
- COL22A1 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 137/391 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355025; called by muse, mutect2, varscan2
- CPAMD8 | c.3472G>C p.A1158P (on ENST00000651564; = p.A1111P on NM_015692.5) | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV71595865; called by muse, mutect2, varscan2
- CR2 | c.1616C>G p.T539S | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.383); catalogued as COSV100889695; called by muse, mutect2, varscan2
- CSMD3 | c.9927C>A p.Y3309* (on ENST00000297405 / NM_001363185.1; = p.Y3140* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 103/406 reads (25%) | catalogued as rs545099108; called by muse, mutect2, varscan2
- CSPG4 | c.4571G>A p.R1524Q | Missense Mutation (SNP) | VAF 159/440 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs140387476, COSV100413583; called by muse, mutect2, varscan2
- CYBB | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 210/576 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV101059742, COSV101059782; called by muse, mutect2, varscan2
- CYP3A4 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 205/952 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs751246524; called by muse, mutect2, varscan2
- DCAF12L1 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 119/339 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV64422169; called by muse, mutect2, varscan2
- DENND3 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52803282; called by muse, mutect2, varscan2
- DMD | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs398123964; called by muse, mutect2, varscan2
- DMXL2 | c.1925A>T p.H642L | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1317987491; called by muse, mutect2, varscan2
- DNAH11 | c.8614C>A p.R2872S | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60973234; called by muse, mutect2, varscan2
- DOK6 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV66934938; called by muse, mutect2, varscan2
- ECT2 | c.2638A>G p.S880G (on ENST00000392692 / NM_001349098.2; = p.S849G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs758541650; called by muse, mutect2
- EDA | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 165/384 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1458684931; called by muse, mutect2, varscan2
- EGFEM1P | n.416-8C>A | Splice Region (SNP) | VAF 32/281 reads (11%) | catalogued as rs866326283; called by muse, mutect2, varscan2
- EGFLAM | c.2639G>A p.R880K (on ENST00000354891 / NM_001205301.2; = p.R872K on NM_152403.4) | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs1179000697; called by muse, mutect2, varscan2
- EPHA5 | c.2621A>G p.Y874C | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268873174; called by muse, mutect2, varscan2
- ERCC3 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 173/459 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760816658; called by muse, mutect2, varscan2
- ERCC6 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 125/835 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63392873; called by muse, mutect2, varscan2
- F2R | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 123/309 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs773332925; called by muse, mutect2, varscan2
- F9 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 83/526 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as CM940449, COSV54382464; called by muse, mutect2, varscan2
- FAM47C | c.2347G>C p.V783L | Missense Mutation (SNP) | VAF 125/446 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); catalogued as COSV63726676; called by muse, mutect2, varscan2
- FAM9B | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.587); catalogued as COSV59119461; called by muse, mutect2, varscan2
- FBXO46 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as rs376962313; called by muse, mutect2, varscan2
- FGFBP3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1215939462; called by muse, mutect2
- G6PD | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM113203, COSV63703292, COSV63704321; called by muse, mutect2, varscan2
- GABRB2 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs193920932, COSV50906596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT12 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs751656135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR143 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 129/440 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV101102290; called by muse, mutect2, varscan2
- HAO2 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | catalogued as COSV58040158; called by muse, mutect2, varscan2
- HECW1 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 64/475 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758956129, COSV67825499; called by muse, mutect2, varscan2
- HEPACAM | c.483C>A p.S161R | Missense Mutation (SNP) | VAF 93/441 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as COSV53429054; called by muse, mutect2, varscan2
- HHIPL1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 214/363 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1344617006, COSV58088978; called by muse, mutect2, varscan2
- HIP1R | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs771064907, COSV99458731; called by muse, mutect2, varscan2
- HIVEP2 | c.7030G>T p.A2344S | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs756648341, COSV99175643; called by muse, mutect2, varscan2
- HS3ST2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs760879006, COSV54461014; called by muse, mutect2, varscan2
- IFNA7 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53331192; called by muse, mutect2, varscan2
- IGKV3-15 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 363/1387 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs757656218; called by muse, mutect2, varscan2
- KCNA4 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV60253776; called by muse, mutect2, varscan2
- KCTD3 | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1367136282, COSV52064391; called by muse, mutect2
- KIF26B | c.4148G>A p.G1383E | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100832152; called by muse, mutect2
- KMT2C | c.12155G>T p.R4052M | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs951610702; called by muse, mutect2, varscan2
- KMT2C | c.5107del p.A1703Lfs*14 | Frame Shift Del (DEL) | VAF 55/224 reads (25%) | catalogued as COSV99031070; called by mutect2, pindel, varscan2
- LAIR1 | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.957); catalogued as rs1270100419, COSV100479840; called by muse, mutect2, varscan2
- LCN9 | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs1380819799; called by muse, mutect2, varscan2
- MAGEB6 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100983655; called by muse, mutect2, varscan2
- MARCHF10 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 179/617 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568081654; called by muse, mutect2, varscan2
- MASP1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 548/924 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV51458649; called by muse, mutect2, varscan2
- MCPH1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs200513127; called by muse, mutect2, varscan2
- MFSD12 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100814872; called by muse, mutect2, varscan2
- MMP16 | c.1766G>C p.R589T | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs765029042, COSV54181143, COSV99690205; called by muse, mutect2, varscan2
- MON1B | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50246344; called by muse, mutect2, varscan2
- NAT16 | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55865490; called by muse, mutect2, varscan2
- NEXMIF | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50129808; called by muse, mutect2, varscan2
- OR1C1 | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 114/551 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101376293; called by muse, mutect2, varscan2
- OR4L1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59849877; called by muse, mutect2, varscan2
- OR5L2 | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 128/515 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1441559778; called by muse, mutect2, varscan2
- ORAI2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104423023; called by muse, mutect2, varscan2
- OTOF | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 95/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs758451807, COSV55522885; called by muse, mutect2, varscan2
- OTOG | c.7236C>A p.C2412* | Nonsense Mutation (SNP) | VAF 57/211 reads (27%) | catalogued as rs1330474897, COSV61134126; called by muse, mutect2, varscan2
- PCDH17 | c.2900C>A p.A967E | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs780263102; called by muse, mutect2, varscan2
- PF4 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56020666; called by muse, mutect2, varscan2
- PIK3CG | c.2179G>C p.A727P | Missense Mutation (SNP) | VAF 234/674 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs767631122; called by muse, mutect2, varscan2
- PLCB4 | c.3057G>T p.Q1019H | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV99595486; called by muse, mutect2, varscan2
- PLVAP | c.187A>C p.T63P | Missense Mutation (SNP) | VAF 125/343 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99391965; called by mutect2, varscan2
- PTCHD3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.362); catalogued as rs780235668, COSV71256703; called by muse, mutect2, varscan2
- RAPGEF2 | c.3157G>T p.G1053* | Nonsense Mutation (SNP) | VAF 98/616 reads (16%) | catalogued as COSV52424344; called by muse, mutect2, varscan2
- RASSF4 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs202044902, COSV58484601; called by muse, mutect2, varscan2
- RIMS2 | c.2815C>T p.P939S (on ENST00000666250 / NM_001348490.2; = p.P747S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs746467834, COSV51676458, COSV99202274; called by muse, mutect2, varscan2
- RYR2 | c.6849G>T p.K2283N | Missense Mutation (SNP) | VAF 169/632 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV63661185; called by muse, mutect2, varscan2
- RYR2 | c.6850G>T p.G2284C | Missense Mutation (SNP) | VAF 170/627 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1358347233, COSV63710725; called by muse, mutect2, varscan2
- SHOC2 | c.1298C>G p.S433* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV54621998; called by muse, mutect2
- SIM1 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV53491155; called by muse, mutect2, varscan2
- SLC26A3 | c.1136del p.G379Dfs*5 | Frame Shift Del (DEL) | VAF 214/1001 reads (21%) | catalogued as CM115267; called by mutect2, pindel, varscan2
- SLITRK4 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV100567368; called by muse, mutect2, varscan2
- SPOPL | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745359213, COSV54511843; called by muse, mutect2, varscan2
- TDRD15 | c.2077A>T p.K693* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as rs780602856; called by muse, mutect2, varscan2
- TLN2 | c.4651G>T p.D1551Y | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs762936331; called by muse, mutect2, varscan2
- TMEM39B | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745507368, COSV60378388; called by muse, mutect2, varscan2
- TTC9B | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs934283850; called by muse, mutect2, varscan2
- TTK | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284768524; called by muse, mutect2
- TTN | c.47770C>A p.H15924N (on ENST00000591111; = p.H8500N on NM_003319.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | PolyPhen benign (0.006); catalogued as rs370126872; called by muse, mutect2, varscan2
- TTN | c.2131C>T p.Q711* (on ENST00000591111; = p.Q665* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/322 reads (3%) | catalogued as COSV100633028; called by muse, mutect2
- TWNK | c.26A>T p.Y9F | Missense Mutation (SNP) | VAF 137/482 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.029); catalogued as COSV52966839; called by muse, mutect2, varscan2
- UNC13B | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1272909050; called by muse, mutect2, varscan2
- VAPB | c.265A>T p.M89L | Missense Mutation (SNP) | VAF 125/573 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs1244452129; called by muse, mutect2, varscan2
- VEGFC | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.87); catalogued as rs1364446269, COSV54593527, COSV54596932; called by muse, mutect2, varscan2
- WDR45 | c.836G>T p.R279L (on ENST00000376372 / NM_001029896.2; = p.R280L on NM_007075.3) | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs782296130, COSV100540228; called by muse, mutect2, varscan2
- WIF1 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV54132497; called by muse, mutect2, varscan2
- WWC3 | c.3192del p.I1065Sfs*10 | Frame Shift Del (DEL) | VAF 45/185 reads (24%) | catalogued as COSV66503941; called by mutect2, pindel, varscan2
- ZBTB33 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58534494; called by muse, mutect2, varscan2
- ZIM2 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV55635971; called by muse, mutect2, varscan2
- ZMYM3 | c.3242A>G p.N1081S | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1472290123; called by muse, mutect2, varscan2
- ZNF629 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 255/563 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV52698638; called by muse, mutect2, varscan2
- ZNF648 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs770294686; called by muse, mutect2, varscan2
- ZNF804B | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1159681068, COSV60818185; called by muse, mutect2, varscan2
- ZNF804B | c.2177G>T p.C726F | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV60827450; called by muse, mutect2
- ABCC9 | c.900T>A p.S300R | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACACB | c.1135A>T p.M379L | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ADAM22 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADGRG4 | c.7297G>T p.G2433C | Missense Mutation (SNP) | VAF 104/544 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRG4 | c.7729G>T p.G2577C | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- AGBL4 | c.10G>C p.G4R | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALKBH7 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ALOX12 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- ANK3 | c.13066C>T p.Q4356* (on ENST00000280772 / NM_001320874.2; = p.Q980* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 50/233 reads (21%) | called by muse, mutect2, varscan2
- ANKRD23 | c.277del p.R93Gfs*24 | Frame Shift Del (DEL) | VAF 150/445 reads (34%) | called by mutect2, pindel, varscan2
- APOB | c.11105T>G p.L3702R | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOO | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ARHGAP11A | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10A | c.4459C>A p.H1487N | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP7B | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAHD1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS4 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 210/737 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BCORL1 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- BHLHE22 | c.770A>T p.D257V | Missense Mutation (SNP) | VAF 96/340 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOD1L2 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C1orf167 | c.4364G>C p.G1455A | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- C6orf226 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1A | c.5867T>A p.L1956H | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASK | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 106/679 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC138 | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC153 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 16/564 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.13); called by muse, mutect2
- CDK5RAP3 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CDKN2A | c.72_90del p.V25Cfs*22 | Frame Shift Del (DEL) | VAF 34/227 reads (15%) | called by mutect2, pindel
- CFAP47 | c.8734G>C p.E2912Q | Missense Mutation (SNP) | VAF 73/396 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CFAP91 | c.2221A>C p.K741Q | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGA4 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- COL22A1 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 170/464 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- COL4A2 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPN2 | c.49A>T p.R17W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- CRYBG2 | c.3955G>C p.V1319L | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CSMD3 | c.7520A>T p.K2507M (on ENST00000297405 / NM_001363185.1; = p.K2403M on NM_052900.3) | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSMD3 | c.6767T>A p.L2256* (on ENST00000297405 / NM_001363185.1; = p.L2152* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 101/400 reads (25%) | called by muse, mutect2, varscan2
- CSMD3 | c.1675T>C p.F559L (on ENST00000297405 / NM_001363185.1; = p.F455L on NM_052900.3) | Missense Mutation (SNP) | VAF 55/445 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- CSNK1A1 | c.375A>T p.E125D | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CTDSPL | c.572G>T p.R191L (on ENST00000273179 / NM_001008392.2; = p.R180L on NM_005808.3) | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNNA3 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CUBN | c.4997A>C p.H1666P | Missense Mutation (SNP) | VAF 80/630 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CUL4B | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CXCR4 | c.534T>A p.S178R | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CXorf21 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DCAF8 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 104/454 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DDB1 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 159/501 reads (32%) | called by muse, mutect2, varscan2
- DEFB123 | c.102C>A p.Y34* | Nonsense Mutation (SNP) | VAF 148/388 reads (38%) | called by muse, mutect2, varscan2
- DLEC1 | c.2195A>T p.H732L | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH17 | c.5434G>T p.E1812* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- DNAJB2 | c.274T>A p.F92I | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DNAJC21 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 116/433 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DRD3 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DROSHA | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ECD | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ENPP2 | c.2085T>G p.D695E (on ENST00000075322 / NM_001040092.3; = p.D747E on NM_006209.5) | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ETS1 | c.147_155del p.C50_P52del | In Frame Del (DEL) | VAF 31/239 reads (13%) | called by mutect2, pindel, varscan2
- F13B | c.1096A>G p.S366G | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM135A | c.2870C>G p.S957C (on ENST00000370479 / NM_001351599.1; = p.S744C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2
- FBN2 | c.6793G>T p.A2265S | Missense Mutation (SNP) | VAF 163/372 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXL14 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FBXL3 | c.452G>C p.S151T | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FBXW7 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCRL3 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FMR1NB | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FSD1L | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 129/444 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FTSJ1 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 221/712 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GABRB3 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 108/436 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- GOT1L1 | c.40C>A p.H14N | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR139 | c.128-1G>A p.X43_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- GRAMD1C | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GREB1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GYS2 | c.1423-1G>C p.X475_splice | Splice Site (SNP) | VAF 121/345 reads (35%) | called by muse, mutect2, varscan2
- HAS1 | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2
- HCN4 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCRTR2 | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 247/575 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- HOXA4 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- HUWE1 | c.8626G>A p.A2876T | Missense Mutation (SNP) | VAF 90/453 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGKV2D-30 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 160/639 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- IKBKB | c.105+7C>A | Splice Region (SNP) | VAF 16/576 reads (3%) | called by muse, mutect2
- INCENP | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- INO80B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- KANSL1 | c.2706T>A p.D902E (on ENST00000574590 / NM_001193465.2; = p.D903E on NM_015443.4) | Missense Mutation (SNP) | VAF 145/490 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNA10 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 81/143 reads (57%) | called by muse, mutect2, varscan2
- KCNC2 | c.1529A>T p.K510M | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- KCNG2 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF19 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KLF8 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- KLHL1 | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- KMT2D | c.13312G>T p.E4438* | Nonsense Mutation (SNP) | VAF 89/200 reads (45%) | called by muse, mutect2, varscan2
- LRCH2 | c.631T>A p.C211S | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- LRCH3 | c.1303A>G p.M435V | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- LRRIQ3 | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM1 | c.1172C>G p.A391G | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LYST | c.7973-2A>T p.X2658_splice | Splice Site (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1743C>A p.H581Q | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- MAP7D2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MARCHF4 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 88/263 reads (33%) | called by muse, mutect2, varscan2
- MAS1 | c.502T>A p.Y168N | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- MBNL2 | c.664A>T p.I222L | Missense Mutation (SNP) | VAF 138/309 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- MED14 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MLXIPL | c.123G>T p.L41F | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MNDA | c.196A>T p.I66L | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MRO | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 143/507 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MUC16 | c.39172C>A p.P13058T | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MUC5AC | c.14073G>T p.Q4691H | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYO16 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MYO1H | c.1007A>T p.H336L | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MYO7A | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 124/510 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NAGS | c.448T>G p.C150G | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NAT9 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEDD4L | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, varscan2
- NKX2-2 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- NKX2-4 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NLRP12 | c.2414A>G p.Q805R | Missense Mutation (SNP) | VAF 145/497 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOL4 | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, varscan2
- NSMCE4A | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- NTM | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- NUFIP1 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- OR10A6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- OR10J5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR4N5 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4P4 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- OR51F1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C68 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- OR8G2P | c.86T>A p.L29H | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OR8H3 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR8H3 | c.524A>T p.H175L | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OR9G1 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTC | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 136/673 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OTOGL | c.2136del p.C713Afs*117 (on ENST00000547103; = p.C704Afs*117 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 319/870 reads (37%) | called by mutect2, pindel, varscan2
- PARP10 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 288/736 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCDHA6 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PCDHB16 | c.2305C>A p.P769T | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE10A | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDE1C | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDE5A | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 68/579 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- POLR3B | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEA | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2
- PPP4R3C | c.1039T>A p.L347I | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PREX2 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 136/586 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRR15 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PSG8 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 76/814 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2
- PSME3 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM19 | c.1277-2A>T p.X426_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- RBMXL3 | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- RELN | c.5661T>A p.S1887R | Missense Mutation (SNP) | VAF 142/569 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RFTN1 | c.955T>A p.L319I | Missense Mutation (SNP) | VAF 181/431 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RFX2 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- RPL36 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RXFP1 | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 40/391 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RYR2 | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCRIB | c.4518G>T p.M1506I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEC31A | c.3202C>T p.Q1068* (on ENST00000355196 / NM_001318120.1; = p.Q1029* on NM_016211.4) | Nonsense Mutation (SNP) | VAF 79/827 reads (10%) | called by muse, mutect2
- SEC62 | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 271/774 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SHISA2 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SHMT2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 127/856 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC14 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIN3B | c.3470G>T p.R1157L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SIPA1L1 | c.3817A>T p.K1273* | Nonsense Mutation (SNP) | VAF 180/325 reads (55%) | called by muse, mutect2, varscan2
- SLC12A7 | c.2452A>G p.T818A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC18A2 | c.1109T>A p.V370D | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SLC22A16 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC49A3 | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC6A1 | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SLCO1B1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMPD4 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX30 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPAM1 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- SPANXN1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 95/577 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SPANXN3 | c.172A>T p.R58W | Missense Mutation (SNP) | VAF 107/439 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SRL | c.95T>C p.L32S | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SRRM5 | c.377_378insC p.R126Sfs*52 | Frame Shift Ins (INS) | VAF 116/334 reads (35%) | called by mutect2, pindel, varscan2
- ST6GAL1 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 61/711 reads (9%) | PolyPhen probably damaging (0.989); called by muse, mutect2
- SUPT3H | c.348C>G p.D116E (on ENST00000371460 / NM_181356.3; = p.D105E on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SYNE1 | c.9503T>C p.L3168P (on ENST00000367255 / NM_182961.4; = p.L3175P on NM_033071.3) | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNJ1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT6 | c.581T>A p.L194H (on ENST00000610222 / NM_001366225.1; = p.L109H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TBC1D5 | c.1002G>C p.W334C | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCHHL1 | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 19/716 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.311); called by muse, mutect2
- TCL1B | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- TCL1B | c.376_377del p.R126Efs*49 | Frame Shift Del (DEL) | VAF 60/148 reads (41%) | called by pindel, varscan2
- THBD | c.1649T>G p.M550R | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TMEM131 | c.5156C>T p.T1719I | Missense Mutation (SNP) | VAF 129/394 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TMEM163 | c.478del p.V160* | Frame Shift Del (DEL) | VAF 51/350 reads (15%) | called by mutect2, pindel, varscan2
- TNFRSF11A | c.782A>T p.K261M | Missense Mutation (SNP) | VAF 302/974 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TNKS1BP1 | c.4961C>T p.S1654L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TNKS1BP1 | c.4960T>C p.S1654P | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TPBGL | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- TRIM72 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TSGA10IP | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC17 | c.3391C>T p.H1131Y | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.65168T>C p.I21723T (on ENST00000591111; = p.I14299T on NM_003319.4) | Missense Mutation (SNP) | VAF 49/163 reads (30%) | PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TTN | c.37213A>T p.I12405F (on ENST00000591111; = p.I4981F on NM_003319.4) | Missense Mutation (SNP) | VAF 113/556 reads (20%) | PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TTN | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 102/314 reads (32%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR17 | c.3450G>T p.L1150F | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- WDR18 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- WDR54 | c.488A>G p.H163R | Missense Mutation (SNP) | VAF 99/572 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YLPM1 | c.6226A>T p.R2076* | Nonsense Mutation (SNP) | VAF 221/491 reads (45%) | called by muse, mutect2, varscan2
- YTHDF3 | c.25-2A>G p.X9_splice | Splice Site (SNP) | VAF 85/308 reads (28%) | called by muse, mutect2, varscan2
- ZBBX | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 137/300 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB42 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZFHX4 | c.6823C>A p.Q2275K | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZFPM2 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZFPM2 | c.2009T>G p.V670G | Missense Mutation (SNP) | VAF 301/1160 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIK1 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ZNF479 | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF676 | c.165dup p.L56Sfs*14 (on ENST00000650058; = p.L24Sfs*14 on NM_001001411.3) | Frame Shift Ins (INS) | VAF 26/179 reads (15%) | called by mutect2, pindel, varscan2
- ZNF721 | c.48A>T p.E16D (on ENST00000338977; = p.E28D on NM_133474.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF783 | c.811T>A p.L271M | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF91 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- ABT1 | c.807C>T p.V269= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV51290895; called by muse, mutect2, varscan2
- ACSM4 | c.1404C>T p.V468= | Silent (SNP) | VAF 147/410 reads (36%) | catalogued as rs1290852605, COSV68068273; called by muse, mutect2, varscan2
- AEBP2 | c.33G>A p.L11= | Silent (SNP) | VAF 98/258 reads (38%) | called by muse, varscan2
- AKAP14 | c.294C>T p.G98= | Silent (SNP) | VAF 37/191 reads (19%) | catalogued as rs1362499527, COSV100538325; called by muse, mutect2, varscan2
- ALKAL2 | c.393T>C p.Y131= | Silent (SNP) | VAF 79/512 reads (15%) | catalogued as rs775186424, COSV55245789; called by muse, mutect2, varscan2
- ALPK1 | c.1659G>T p.V553= | Silent (SNP) | VAF 97/270 reads (36%) | called by muse, mutect2, varscan2
- ANK1 | c.1131C>A p.I377= | Silent (SNP) | VAF 258/817 reads (32%) | catalogued as rs373336198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP4 | c.375G>A p.G125= | Silent (SNP) | VAF 221/879 reads (25%) | catalogued as rs757028911, COSV67218700; called by muse, mutect2, varscan2
- ARHGEF10L | c.2541C>T p.P847= | Silent (SNP) | VAF 125/255 reads (49%) | catalogued as rs747392737; called by muse, mutect2, varscan2
- ARHGEF5 | c.999A>T p.P333= | Silent (SNP) | VAF 272/1398 reads (19%) | called by muse, mutect2, varscan2
- ATP10B | c.3885C>T p.N1295= | Silent (SNP) | VAF 177/427 reads (41%) | called by muse, mutect2, varscan2
- BCOR | c.3486C>G p.R1162= | Silent (SNP) | VAF 189/523 reads (36%) | called by muse, mutect2, varscan2
- BRF1 | c.229C>T p.L77= | Silent (SNP) | VAF 23/538 reads (4%) | called by muse, mutect2
- BTAF1 | c.2979A>T p.A993= | Silent (SNP) | VAF 45/293 reads (15%) | called by muse, mutect2, varscan2
- C1QC | c.516G>A p.A172= | Silent (SNP) | VAF 58/248 reads (23%) | catalogued as rs369658525; called by muse, mutect2, varscan2
- CCDC7 | c.4047C>T p.S1349= | Silent (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- CEACAM21 | c.87C>T p.N29= | Silent (SNP) | VAF 201/627 reads (32%) | catalogued as rs545179785, COSV51815274; called by muse, mutect2, varscan2
- CFAP70 | c.1584A>G p.E528= | Silent (SNP) | VAF 39/226 reads (17%) | catalogued as rs747174149; called by muse, mutect2, varscan2
- COL10A1 | c.1254T>A p.P418= | Silent (SNP) | VAF 119/269 reads (44%) | called by muse, mutect2, varscan2
- CPA5 | c.228C>A p.P76= | Silent (SNP) | VAF 64/198 reads (32%) | called by muse, mutect2, varscan2
- CREB3L2 | c.456G>T p.P152= | Silent (SNP) | VAF 135/464 reads (29%) | called by muse, mutect2, varscan2
- CRYBB1 | c.720G>A p.E240= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as rs1159876937; called by muse, mutect2, varscan2
- DCDC1 | c.3834T>A p.T1278= (on ENST00000597505 / NM_001367979.1; = p.T385= on NM_020869.3) | Silent (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- DNAH5 | c.8769C>T p.G2923= | Silent (SNP) | VAF 162/513 reads (32%) | catalogued as rs546765121, COSV54254658; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH7 | c.5121G>T p.L1707= | Silent (SNP) | VAF 109/452 reads (24%) | catalogued as COSV56756788; called by muse, mutect2, varscan2
- DOK6 | c.954C>A p.S318= | Silent (SNP) | VAF 82/421 reads (19%) | called by muse, mutect2, varscan2
- DYSF | c.3115C>A p.R1039= | Silent (SNP) | VAF 80/355 reads (23%) | catalogued as COSV99245862; called by muse, mutect2, varscan2
- ESR1 | c.519T>C p.S173= | Silent (SNP) | VAF 32/477 reads (7%) | called by muse, mutect2
- ETV2 | c.480C>A p.P160= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV55837150; called by muse, mutect2, varscan2
- F5 | c.1941T>A p.R647= | Silent (SNP) | VAF 257/867 reads (30%) | called by muse, mutect2, varscan2
- FAM47C | c.2019T>C p.T673= | Silent (SNP) | VAF 116/325 reads (36%) | called by muse, mutect2, varscan2
- FHL5 | c.324C>A p.T108= | Silent (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2
- GATA3 | c.1221G>T p.S407= | Silent (SNP) | VAF 54/256 reads (21%) | called by muse, mutect2, varscan2
- GGT7 | c.174G>A p.P58= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- GNAS | c.585C>T p.P195= | Silent (SNP) | VAF 79/343 reads (23%) | catalogued as rs747319359; called by muse, mutect2, varscan2
- GNL3L | c.783C>A p.P261= | Silent (SNP) | VAF 94/315 reads (30%) | called by muse, mutect2, varscan2
- GPR183 | c.612A>T p.G204= | Silent (SNP) | VAF 148/337 reads (44%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1419G>A p.K473= | Silent (SNP) | VAF 59/212 reads (28%) | called by muse, mutect2, varscan2
- HARS1 | c.201C>G p.P67= | Silent (SNP) | VAF 126/257 reads (49%) | catalogued as COSV56907367; called by muse, mutect2, varscan2
- HUWE1 | c.8625A>C p.S2875= | Silent (SNP) | VAF 93/458 reads (20%) | called by muse, mutect2, varscan2
- IFITM1 | c.159C>T p.G53= | Silent (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- IGF1R | c.1050C>T p.L350= | Silent (SNP) | VAF 175/598 reads (29%) | catalogued as rs1419252480, COSV51374912; called by muse, mutect2, varscan2
- IGFALS | c.1578G>A p.P526= | Silent (SNP) | VAF 48/207 reads (23%) | catalogued as rs774115726; called by muse, mutect2, varscan2
- JAKMIP1 | c.117G>A p.Q39= | Silent (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- KANK1 | c.3645G>T p.R1215= | Silent (SNP) | VAF 114/396 reads (29%) | called by muse, mutect2, varscan2
- KCNK2 | c.1206T>A p.T402= (on ENST00000444842 / NM_001017425.3; = p.T387= on NM_014217.4) | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- KLHL5 | c.447A>G p.A149= | Silent (SNP) | VAF 40/286 reads (14%) | called by muse, mutect2, varscan2
- KLK13 | c.468C>T p.T156= | Silent (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- KRT39 | c.627G>C p.L209= | Silent (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- LRIT3 | c.432G>T p.V144= | Silent (SNP) | VAF 57/346 reads (16%) | called by muse, mutect2, varscan2
- LRRC18 | c.93C>T p.R31= | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- LRRC69 | c.735G>A p.E245= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as COSV59253272; called by muse, mutect2, varscan2
- LSM5 | c.234T>C p.N78= | Silent (SNP) | VAF 128/383 reads (33%) | called by muse, mutect2, varscan2
- MAGEB6 | c.597G>T p.A199= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV66871971; called by muse, mutect2, varscan2
- MCTP1 | c.738T>A p.A246= | Silent (SNP) | VAF 86/214 reads (40%) | called by muse, mutect2, varscan2
- MKRN1 | c.957T>C p.S319= | Silent (SNP) | VAF 28/468 reads (6%) | catalogued as rs757426959; called by muse, mutect2
- MPP1 | c.1371A>G p.P457= | Silent (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- MS4A6A | c.309C>A p.I103= | Silent (SNP) | VAF 88/344 reads (26%) | catalogued as rs202077172; called by muse, mutect2
- MTPAP | c.6G>C p.A2= | Silent (SNP) | VAF 58/290 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.7848C>A p.T2616= | Silent (SNP) | VAF 56/301 reads (19%) | called by muse, mutect2, varscan2
- NCAPD3 | c.9G>T p.A3= | Silent (SNP) | VAF 83/303 reads (27%) | catalogued as rs771146558; called by muse, mutect2, varscan2
- NEXMIF | c.831C>G p.S277= | Silent (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- NIBAN2 | c.73C>T p.L25= | Silent (SNP) | VAF 104/250 reads (42%) | catalogued as COSV64824295; called by muse, mutect2, varscan2
- NID1 | c.168C>T p.A56= | Silent (SNP) | VAF 83/285 reads (29%) | called by muse, mutect2, varscan2
- NINL | c.3000G>T p.R1000= | Silent (SNP) | VAF 152/355 reads (43%) | called by muse, mutect2, varscan2
- NPC1L1 | c.492T>C p.F164= | Silent (SNP) | VAF 140/416 reads (34%) | called by muse, mutect2, varscan2
- OPRK1 | c.174C>A p.I58= | Silent (SNP) | VAF 122/450 reads (27%) | catalogued as COSV99653860; called by muse, mutect2, varscan2
- OR10A6 | c.480A>T p.T160= | Silent (SNP) | VAF 100/428 reads (23%) | catalogued as COSV59166375; called by muse, mutect2, varscan2
- OR2T2 | c.66T>A p.P22= | Silent (SNP) | VAF 289/1932 reads (15%) | catalogued as COSV61618886; called by muse, mutect2, varscan2
- OR2T35 | c.66T>A p.P22= | Silent (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2
- OR7G2 | c.16C>T p.L6= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs150102898; called by muse, mutect2, varscan2
- PACS1 | c.669G>A p.Q223= | Silent (SNP) | VAF 89/233 reads (38%) | called by muse, mutect2, varscan2
- PAX8 | c.906C>T p.H302= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as rs750725540; called by muse, varscan2
- PCDHA2 | c.603C>T p.D201= | Silent (SNP) | VAF 98/214 reads (46%) | called by muse, mutect2, varscan2
- PDE7A | c.255C>T p.H85= (on ENST00000401827 / NM_001242318.3; = p.H59= on NM_002603.4) | Silent (SNP) | VAF 61/230 reads (27%) | catalogued as rs757988332; called by muse, mutect2, varscan2
- PHF8 | c.384G>T p.R128= (on ENST00000357988 / NM_001184896.1; = p.R92= on NM_015107.3) | Silent (SNP) | VAF 134/518 reads (26%) | called by muse, mutect2, varscan2
- PIP4K2A | c.831G>T p.L277= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- PLVAP | c.186C>A p.A62= | Silent (SNP) | VAF 126/343 reads (37%) | called by mutect2, varscan2
- PRDM9 | c.843A>T p.T281= | Silent (SNP) | VAF 119/423 reads (28%) | called by muse, mutect2, varscan2
- PROX1 | c.1125C>A p.P375= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- PRSS22 | c.609C>A p.I203= | Silent (SNP) | VAF 53/349 reads (15%) | catalogued as COSV50721019; called by muse, mutect2, varscan2
- PSG8 | c.417C>T p.T139= | Silent (SNP) | VAF 20/217 reads (9%) | catalogued as rs750621396; called by muse, mutect2
- RANBP2 | c.4932A>C p.T1644= | Silent (SNP) | VAF 247/907 reads (27%) | catalogued as rs200526519; called by muse, varscan2
- RASL10B | c.129G>C p.L43= | Silent (SNP) | VAF 114/472 reads (24%) | called by muse, mutect2, varscan2
- RBM42 | c.855G>T p.P285= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- REX1BD | c.363G>T p.V121= | Silent (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- SALL3 | c.537G>T p.A179= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as rs1160146004; called by muse, mutect2, varscan2
- SH3PXD2B | c.1686G>C p.P562= | Silent (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- SHISA9 | c.153C>T p.S51= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs568551769, COSV69635567; called by muse, mutect2, varscan2
- SHROOM3 | c.3399C>T p.L1133= | Silent (SNP) | VAF 54/362 reads (15%) | catalogued as rs1397254616; called by muse, mutect2, varscan2
- SLC26A9 | c.765G>A p.S255= | Silent (SNP) | VAF 21/362 reads (6%) | catalogued as rs769714824; called by muse, mutect2
- SLC28A3 | c.57C>T p.F19= | Silent (SNP) | VAF 121/343 reads (35%) | catalogued as rs989410709; called by muse, mutect2, varscan2
- SLC38A10 | c.3291G>T p.A1097= | Silent (SNP) | VAF 108/396 reads (27%) | catalogued as rs748593275, COSV66100669; called by muse, mutect2, varscan2
- SLC6A17 | c.1623C>A p.I541= | Silent (SNP) | VAF 99/226 reads (44%) | catalogued as rs775614013, COSV58992260; called by muse, mutect2, varscan2
- SOX3 | c.1146G>T p.P382= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV65168418; called by muse, mutect2, varscan2
- TBC1D30 | c.387C>A p.G129= | Silent (SNP) | VAF 54/93 reads (58%) | called by muse, mutect2, varscan2
- TMX3 | c.315A>G p.L105= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as rs1282253179; called by muse, mutect2, varscan2
- TNNT2 | c.288C>T p.D96= | Silent (SNP) | VAF 138/333 reads (41%) | catalogued as COSV52664543; called by muse, mutect2, varscan2
- TRO | c.3795C>A p.T1265= | Silent (SNP) | VAF 93/316 reads (29%) | called by muse, mutect2, varscan2
- VSTM5 | c.363C>A p.T121= | Silent (SNP) | VAF 112/331 reads (34%) | called by muse, mutect2, varscan2
- ZIK1 | c.339G>A p.L113= | Silent (SNP) | VAF 93/399 reads (23%) | called by muse, mutect2, varscan2
- ZNF490 | c.855A>G p.K285= | Silent (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- ZNF709 | c.1402A>C p.R468= | Silent (SNP) | VAF 42/226 reads (19%) | called by muse, varscan2
- ZNF747 | c.114C>T p.S38= | Silent (SNP) | VAF 39/277 reads (14%) | catalogued as rs763807489; called by muse, mutect2, varscan2
- ZNF80 | c.60G>A p.Q20= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- ZNFX1 | c.2652A>T p.T884= | Silent (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2
- AC073310.1 | n.299G>C | RNA (SNP) | VAF 131/472 reads (28%) | catalogued as rs746939789; called by muse, mutect2, varscan2
- AC079395.2 | n.51T>A | RNA (SNP) | VAF 76/203 reads (37%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-11355G>C | Intron (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2, varscan2
- AP003062.1 | n.742G>C | RNA (SNP) | VAF 132/1240 reads (11%) | called by muse, varscan2
- AP3B2 | c.2441-41C>A | Intron (SNP) | VAF 190/659 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.502-315C>A | Intron (SNP) | VAF 33/106 reads (31%) | catalogued as COSV50149443; called by muse, mutect2, varscan2
- C1orf146 | c.*4_*16del | 3'UTR (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- C22orf34 | n.162G>T | RNA (SNP) | VAF 68/339 reads (20%) | catalogued as rs1009242796; called by muse, mutect2, varscan2
- C5orf22 | c.1060-2727G>A | Intron (SNP) | VAF 61/215 reads (28%) | called by muse, mutect2, varscan2
- CEP170P1 | n.1981G>A | RNA (SNP) | VAF 30/478 reads (6%) | catalogued as rs1323561384; called by muse, mutect2
- CORO1A | c.756+32C>A | Intron (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
- CRYAB | c.325-279A>T | Intron (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101558202 G>T | 5'Flank (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- ERBB4 | c.*50C>T | 3'UTR (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- GVINP1 | n.3760G>T | RNA (SNP) | VAF 62/244 reads (25%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+1859G>C | Intron (SNP) | VAF 236/424 reads (56%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1673C>A | RNA (SNP) | VAF 58/299 reads (19%) | called by mutect2, varscan2
- IGDCC4 | c.3180+64A>G | Intron (SNP) | VAF 106/412 reads (26%) | called by muse, mutect2
- IL2RG | c.925-43C>A | Intron (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- JAK3 | c.-13-21C>A | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- L1CAM | c.3458-48G>A | Intron (SNP) | VAF 68/276 reads (25%) | catalogued as rs200396267; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85689del | Intron (DEL) | VAF 150/780 reads (19%) | called by mutect2, pindel, varscan2
- MIR29B2CHG | n.371G>T | RNA (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- MIR30C2 | chr6:71376892 C>A | 3'Flank (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- MUC19 | c.163-11C>A | Intron (SNP) | VAF 63/415 reads (15%) | called by muse, mutect2, varscan2
- MUC19 | c.163-10C>A | Intron (SNP) | VAF 64/424 reads (15%) | called by muse, mutect2, varscan2
- NAV1 | c.3406-219G>T | Intron (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- NBPF20 | c.*7C>A | 3'UTR (SNP) | VAF 196/680 reads (29%) | catalogued as COSV100978816; called by muse, varscan2
- NRXN1 | c.4039-30317G>A | Intron (SNP) | VAF 309/688 reads (45%) | catalogued as rs1029113014; called by muse, mutect2, varscan2
- P2RX5 | c.138-21G>T | Intron (SNP) | VAF 57/116 reads (49%) | catalogued as rs774534125, COSV99835530; called by muse, varscan2
- PAQR9 | chr3:142952820 A>T | 3'Flank (SNP) | VAF 185/439 reads (42%) | called by muse, mutect2, varscan2
- PPA2 | c.157+344C>T | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as rs750214417; called by muse, mutect2, varscan2
- RBMXL2 | c.-50G>C | 5'UTR (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100182408; called by muse, mutect2, varscan2
- RGS10 | c.-2C>T | 5'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559292 C>A | 5'Flank (SNP) | VAF 218/860 reads (25%) | called by muse, mutect2, varscan2
- SDHAF2 | c.-3A>C | 5'UTR (SNP) | VAF 155/528 reads (29%) | called by muse, mutect2, varscan2
- SEPSECS | c.115-436A>G | Intron (SNP) | VAF 37/141 reads (26%) | catalogued as rs1428464594; called by muse, mutect2, varscan2
- SLC25A25 | c.1226-38C>T | Intron (SNP) | VAF 17/162 reads (10%) | catalogued as rs148031706; called by muse, mutect2
- SMARCAD1 | c.*1444T>C | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- SNORD116-18 | chr15:25088705 A>G | 3'Flank (SNP) | VAF 90/469 reads (19%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25091981 G>T | 3'Flank (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- SNX22 | c.159+9G>A | Intron (SNP) | VAF 47/145 reads (32%) | catalogued as rs889983194; called by muse, mutect2, varscan2
- SPTBN2 | c.5566-35C>T | Intron (SNP) | VAF 12/29 reads (41%) | catalogued as rs1270556674; called by muse, mutect2, varscan2
- SYNCRIP | chr6:85612911 C>A | 3'Flank (SNP) | VAF 92/310 reads (30%) | catalogued as COSV62289609; called by muse, mutect2, varscan2
- TFE3 | c.*42G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- TRIM51EP | n.775C>A | RNA (SNP) | VAF 139/945 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.34265-3229G>T | Intron (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- U82695.1 | n.1554C>G | RNA (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- UBE2A | c.-75G>T | 5'UTR (SNP) | VAF 59/308 reads (19%) | called by muse, mutect2, varscan2
- WASF4P | n.550G>C | RNA (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- WASF4P | n.667G>C | RNA (SNP) | VAF 228/658 reads (35%) | called by muse, mutect2, varscan2
- XAGE5 | c.179-861C>G | Intron (SNP) | VAF 60/263 reads (23%) | called by muse, mutect2, varscan2
